Somatic mutation profile of tumor specimen TCGA-W2-A7HA-01B (aliquot TCGA-W2-A7HA-01B-11D-A35I-08) from TCGA case TCGA-W2-A7HA, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 63.1 years (23,059 days).
Specimen TCGA-W2-A7HA-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66151379-0466-45fe-be67-bcd34b02200d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W2-A7HA-10C (Blood Derived Normal), aliquot TCGA-W2-A7HA-10C-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6610a18-f108-46a9-8f18-5cf53a740602

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LTBP1 | c.1639G>A p.V547I (on ENST00000404816 / NM_206943.4; = p.V221I on NM_000627.4) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs749052544, COSV100618122; called by muse, mutect2, varscan2
- MMP2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs758315277; called by muse, mutect2, varscan2
- SYT3 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.16); catalogued as rs777689783, COSV58898457; called by muse, mutect2, varscan2
- TNKS | c.3854A>G p.N1285S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs767692118, COSV60051672; called by muse, varscan2
- ADCY10 | c.3760G>A p.A1254T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- BRWD3 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CASP2 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCL13 | c.242G>C p.W81S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJA5 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- HAVCR1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HSP90AA1 | c.581A>C p.Q194P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MCOLN2 | c.176G>T p.R59I | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBC1D10C | c.1329C>G p.D443E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WNT3 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); called by muse, mutect2
- ARL2 | c.15C>T p.T5= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- GPR148 | c.63C>T p.L21= | Silent (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- HELZ | c.5628G>A p.A1876= | Silent (SNP) | VAF 94/233 reads (40%) | catalogued as rs745477812; called by muse, mutect2, varscan2
- MSLN | c.1236T>G p.P412= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV53499919; called by muse, mutect2, varscan2
- RWDD4 | c.195C>T p.N65= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs781607096, COSV100419120; called by muse, mutect2, varscan2
- TBC1D1 | c.1800C>T p.F600= | Silent (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- THBS1 | c.2865C>T p.T955= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs139289744; called by mutect2, varscan2
